Somatic mutation profile of tumor specimen ALCH-ADW5-TTP1-A (aliquot ALCH-ADW5-TTP1-A-1-0-D-A587-36) from ALCHEMIST case ALCH-ADW5, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 64.7 years (23,639 days).
Specimen ALCH-ADW5-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 324630d0-39cc-486d-a26c-4c33933f9a3f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-ADW5-NB1-A (Blood Derived Normal), aliquot ALCH-ADW5-NB1-A-1-0-D-A587-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3a69d704-16b9-4af5-bede-3b60bf540853

The open-access MAF lists 54 somatic variants for this specimen: 36 protein-altering or splice-affecting, 6 silent, 12 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 29, Silent 6, Intron 5, Nonsense Mutation 4, 3'UTR 2, Frame Shift Del 2, RNA 2, 5'UTR 2, 5'Flank 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1526G>T p.G509V (on ENST00000288602 / NM_001374244.1; = p.G469V on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 63/507 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121913355, CM060876, COSV56061424, COSV56062352, COSV56065622; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.725G>A p.C242Y | Missense Mutation (SNP) | VAF 85/407 reads (21%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121912655, CM910618, COSV52661189, COSV52677418, COSV52689710; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ABCB10 | c.2032C>T p.R678* | Nonsense Mutation (SNP) | VAF 144/436 reads (33%) | catalogued as rs1370648698; called by muse, mutect2, varscan2
- APBA1 | c.334C>T p.P112S | Missense Mutation (SNP) | VAF 15/125 reads (12%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.017); catalogued as COSV55223314; called by muse, mutect2, varscan2
- CDH19 | c.985C>T p.H329Y | Missense Mutation (SNP) | VAF 29/189 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.021); catalogued as rs758808369; called by muse, mutect2, varscan2
- CPNE3 | c.1423C>T p.R475C | Missense Mutation (SNP) | VAF 96/574 reads (17%) | SIFT tolerated (0.12); PolyPhen benign (0.031); catalogued as rs754124587; called by muse, mutect2, varscan2
- IRS2 | c.1684G>A p.D562N | Missense Mutation (SNP) | VAF 27/218 reads (12%) | SIFT tolerated (0.05); PolyPhen benign (0.202); catalogued as COSV65477091; called by muse, mutect2, varscan2
- KRT34 | c.1022C>T p.T341M | Missense Mutation (SNP) | VAF 31/375 reads (8%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.746); catalogued as rs754757891, COSV67450018; called by muse, mutect2
- MYH2 | c.521C>G p.S174* | Nonsense Mutation (SNP) | VAF 93/447 reads (21%) | catalogued as COSV55433727; called by muse, mutect2, varscan2
- PCDHA13 | c.1787C>T p.A596V | Missense Mutation (SNP) | VAF 44/490 reads (9%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.858); catalogued as rs782119019; called by muse, mutect2
- PLXNA4 | c.3476C>T p.T1159M | Missense Mutation (SNP) | VAF 38/221 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.709); catalogued as rs774798274, COSV58110834; called by muse, mutect2, varscan2
- RPL13A | c.221G>A p.R74Q | Missense Mutation (SNP) | VAF 86/408 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.145); catalogued as rs1332523202; called by muse, mutect2, varscan2
- SLC26A7 | c.614A>T p.Y205F | Missense Mutation (SNP) | VAF 51/211 reads (24%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.533); catalogued as COSV52604792; called by muse, mutect2, varscan2
- STK11 | c.560del p.G187Vfs*100 | Frame Shift Del (DEL) | VAF 25/106 reads (24%) | catalogued as COSV58827697; called by mutect2, pindel, varscan2
- ACOX3 | c.237_253del p.C82Vfs*2 | Frame Shift Del (DEL) | VAF 83/584 reads (14%) | called by mutect2, pindel, varscan2
- ANKRD11 | c.3932dup p.G1312Rfs*31 | Frame Shift Ins (INS) | VAF 44/309 reads (14%) | called by mutect2, pindel, varscan2
- ASIC2 | c.151G>T p.G51C | Missense Mutation (SNP) | VAF 91/478 reads (19%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.889); called by muse, mutect2, varscan2
- CCT4 | c.1078G>T p.E360* | Nonsense Mutation (SNP) | VAF 54/367 reads (15%) | called by muse, mutect2, varscan2
- CHSY3 | c.1571A>G p.Y524C | Missense Mutation (SNP) | VAF 50/351 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- DDO | c.784G>C p.E262Q (on ENST00000368924 / NM_001368172.1; = p.E203Q on NM_004032.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 27/150 reads (18%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- DMGDH | c.839A>G p.E280G | Missense Mutation (SNP) | VAF 51/359 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.015); called by muse, mutect2
- FKBP15 | c.3201G>T p.M1067I | Missense Mutation (SNP) | VAF 57/338 reads (17%) | SIFT tolerated, low confidence (0.47); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- HECW2 | c.2561A>T p.Q854L | Missense Mutation (SNP) | VAF 22/142 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.977); called by muse, mutect2
- MS4A15 | c.583T>G p.C195G (on ENST00000405633 / NM_001098835.2; = p.C102G on NM_152717.3) | Missense Mutation (SNP) | VAF 60/444 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- MYO18B | c.3800C>T p.T1267I | Missense Mutation (SNP) | VAF 79/416 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.151); called by muse, mutect2, varscan2
- MYO7B | c.2087C>T p.T696M | Missense Mutation (SNP) | VAF 71/464 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.944); called by muse, mutect2, varscan2
- PALMD | c.1555C>T p.H519Y | Missense Mutation (SNP) | VAF 34/165 reads (21%) | SIFT tolerated (0.08); PolyPhen benign (0.133); called by muse, mutect2, varscan2
- PDHX | c.619C>T p.P207S | Missense Mutation (SNP) | VAF 76/438 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.464); called by muse, mutect2, varscan2
- PRRX1 | c.274A>G p.R92G | Missense Mutation (SNP) | VAF 117/797 reads (15%) | SIFT tolerated (0.16); PolyPhen benign (0.067); called by muse, mutect2, varscan2
- PRSS23 | c.1079G>C p.R360T | Missense Mutation (SNP) | VAF 38/225 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- RAB3C | c.433T>A p.C145S | Missense Mutation (SNP) | VAF 52/275 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.107); called by muse, mutect2, varscan2
- SLC5A2 | c.92C>T p.A31V | Missense Mutation (SNP) | VAF 166/904 reads (18%) | SIFT tolerated (0.79); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SNX30 | c.361G>C p.E121Q | Missense Mutation (SNP) | VAF 21/207 reads (10%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- SPEN | c.9086G>A p.S3029N | Missense Mutation (SNP) | VAF 27/136 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.159); called by muse, mutect2, varscan2
- TSEN54 | c.514C>T p.Q172* | Nonsense Mutation (SNP) | VAF 85/530 reads (16%) | called by muse, mutect2, varscan2
- WASHC4 | c.720A>T p.K240N | Missense Mutation (SNP) | VAF 64/307 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.693); called by muse, mutect2, varscan2
- DCLRE1C | c.1416T>C p.D472= (on ENST00000378278 / NM_001350965.2; = p.D357= on NM_022487.4) | Silent (SNP) | VAF 30/122 reads (25%) | called by muse, mutect2, varscan2
- DNAI2 | c.69C>G p.R23= | Silent (SNP) | VAF 78/467 reads (17%) | catalogued as COSV56759069; called by muse, mutect2, varscan2
- KLHL1 | c.171C>G p.L57= | Silent (SNP) | VAF 17/120 reads (14%) | catalogued as COSV64766964, COSV64777483; called by muse, mutect2, varscan2
- OR10D3 | c.513C>A p.P171= | Silent (SNP) | VAF 87/571 reads (15%) | catalogued as COSV100591085; called by muse, mutect2, varscan2
- SPEN | c.9087T>C p.S3029= | Silent (SNP) | VAF 27/134 reads (20%) | called by muse, mutect2, varscan2
- TSC2 | c.411C>T p.H137= | Silent (SNP) | VAF 31/392 reads (8%) | catalogued as rs776129896; ClinVar: likely benign / benign; called by muse, mutect2
- AC022182.2 | n.192G>T | RNA (SNP) | VAF 26/105 reads (25%) | called by mutect2, varscan2
- ASIC4 | c.1018+38del | Intron (DEL) | VAF 5/35 reads (14%) | catalogued as rs1226857343; called by mutect2, pindel, varscan2
- BRD9 | c.401-48A>T | Intron (SNP) | VAF 76/402 reads (19%) | called by muse, mutect2, varscan2
- C15orf48 | c.*54T>G | 3'UTR (SNP) | VAF 66/403 reads (16%) | catalogued as COSV100721054; called by muse, mutect2, varscan2
- DTNBP1 | c.811+45T>C | Intron (SNP) | VAF 18/89 reads (20%) | catalogued as rs1395969772; called by muse, mutect2, varscan2
- FOXI2 | chr10:127736548 G>A | 5'Flank (SNP) | VAF 30/152 reads (20%) | catalogued as rs1182243711; called by muse, mutect2, varscan2
- GLYATL1 | n.363C>T | RNA (SNP) | VAF 60/274 reads (22%) | called by muse, varscan2
- GTF3C2 | c.*453T>G | 3'UTR (SNP) | VAF 33/174 reads (19%) | called by muse, mutect2, varscan2
- RELCH | c.617-41G>C | Intron (SNP) | VAF 57/449 reads (13%) | called by muse, mutect2, varscan2
- RPL10 | c.-49T>C | 5'UTR (SNP) | VAF 102/344 reads (30%) | called by muse, mutect2, varscan2
- TMEM209 | c.3+16C>T | Intron (SNP) | VAF 107/454 reads (24%) | catalogued as rs761247080; called by muse, mutect2, varscan2
- TUB | c.-1G>A | 5'UTR (SNP) | VAF 12/97 reads (12%) | catalogued as rs931180847, COSV100538911, COSV59487832; called by muse, mutect2
